Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A4NF, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A4NF-01A (Primary Tumor).

DIAGNOSIS:

A. Gallbladder, cholecystectomy: Chronic cholecystitis with cholelithiasis and cholesterosis. One benign lymph node identified.

B. Liver, segment 8, wedge biopsy: Moderately differentiated hepatocellular carcinoma, forming a single 3.2 x 2.9 x 2.8 cm mass. Vascular invasion is not identified. Surgical margins are negative for tumor (closest margin, 0.6 cm). The background liver shows mildly active (grade 2 of 4) chronic hepatitis C with bridging fibrosis and early cirrhosis (stage 3-4 of 6).

With available surgical material [AJCC pT1] (7th edition,

ADDENDUM:

Reticulin and trichrome stains support the above diagnosis.

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

JW 12/24/12

9/20/12

Source: NCI Genomic Data Commons file 0ac9fe17-f322-4ae6-a1f0-3c5de2e33fe4 (TCGA-DD-A4NF.7381633C-866A-4440-93B1-BC7102B59C93.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).